CCDI case PBCGFA — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Meningiomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/129361e3-f3aa-43d7-9b4d-d84d17b85604

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Meningioma, NOS: ICD-O-3 morphology code: 9530/0; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.4 years (4,156 days).

Biospecimens (3 samples)
- Sample 0DS8G7: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DS8GJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DS8GS: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
